Somatic mutation profile of tumor specimen ALCH-AEE1-TTP1-A (aliquot ALCH-AEE1-TTP1-A-1-0-D-A627-36) from ALCHEMIST case ALCH-AEE1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.2 years (23,812 days).
Specimen ALCH-AEE1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73f2a628-725b-4f74-8443-af518ac43bfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEE1-NB1-A (Blood Derived Normal), aliquot ALCH-AEE1-NB1-A-2-0-D-A628-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cf2344a-b711-465c-8a6b-28427dd6ec92

The open-access MAF lists 302 somatic variants for this specimen: 210 protein-altering or splice-affecting, 63 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 63, Intron 16, Nonsense Mutation 13, Frame Shift Del 13, Splice Site 5, 3'Flank 4, Splice Region 3, RNA 3, Frame Shift Ins 3, 3'UTR 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KEAP1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 63/339 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV50260643, COSV50262012; called by muse, mutect2, varscan2
- STK11 | c.157dup p.D53Gfs*110 | Frame Shift Ins (INS) | VAF 68/402 reads (17%) | catalogued as rs1131690917; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ADGB | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 57/487 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1344052718; called by muse, mutect2, varscan2
- ADGB | c.4471G>T p.E1491* | Nonsense Mutation (SNP) | VAF 95/613 reads (15%) | catalogued as COSV58850983; called by muse, mutect2, varscan2
- AFF2 | c.3707C>A p.P1236H | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54009275; called by muse, mutect2
- AP5B1 | c.1825C>T p.R609C | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs769973921; called by mutect2, varscan2
- ASTN1 | c.2054+2T>A p.X685_splice | Splice Site (SNP) | VAF 27/252 reads (11%) | catalogued as COSV56063445, COSV99920863; called by muse, mutect2, varscan2
- ASZ1 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 45/318 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99498016; called by muse, mutect2, varscan2
- ATG2A | c.1966C>A p.P656T | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747149594, COSV65966001; called by muse, mutect2, varscan2
- BCAN | c.1282C>A p.P428T | Missense Mutation (SNP) | VAF 16/120 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.922); catalogued as COSV61258915; called by muse, mutect2, varscan2
- CARS1 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 70/391 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV53454307; called by muse, mutect2, varscan2
- CCDC22 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs868906549; called by muse, varscan2
- CEACAM18 | c.407del p.G136Efs*35 | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | catalogued as COSV67283797; called by mutect2, pindel
- CERKL | c.38T>A p.L13Q | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.029); catalogued as COSV59209296; called by muse, mutect2, varscan2
- CNTN6 | c.536del p.G179Efs*20 | Frame Shift Del (DEL) | VAF 38/373 reads (10%) | catalogued as COSV63164796; called by mutect2, pindel, varscan2
- CNTNAP2 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs1462976869; called by muse, mutect2, varscan2
- COL7A1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 75/510 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.568); catalogued as rs776805869, COSV60399353; called by muse, mutect2, varscan2
- DLGAP3 | c.911G>A p.R304H | Missense Mutation (SNP) | VAF 55/311 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as rs773502530, COSV52392258, COSV52396866, COSV99332347; called by muse, mutect2, varscan2
- ECT2L | c.986T>C p.I329T | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs573565313; called by muse, mutect2, varscan2
- ELMOD1 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs201524635; called by muse, mutect2, varscan2
- EMILIN2 | c.1239C>A p.D413E | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.298); catalogued as rs867486175; called by muse, mutect2
- ENPP2 | c.728A>T p.H243L | Missense Mutation (SNP) | VAF 45/314 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV50019233; called by muse, mutect2, varscan2
- EPHA10 | c.292G>A p.G98R | Missense Mutation (SNP) | VAF 23/234 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762731131; called by muse, mutect2
- EYA3 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs781423829; called by muse, mutect2
- FAM72A | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 43/444 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs782163193; called by muse, mutect2
- FSIP2 | c.5201C>A p.A1734E | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1183421331; called by muse, mutect2, varscan2
- GJB3 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 108/699 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs143866277; called by muse, mutect2, varscan2
- GRID1 | c.1641G>T p.K547N | Missense Mutation (SNP) | VAF 45/332 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100022507; called by muse, mutect2, varscan2
- ITGAV | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs771768690; called by muse, mutect2, varscan2
- JAKMIP2 | c.1488G>T p.Q496H | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); catalogued as COSV54608906; called by muse, mutect2, varscan2
- KCNA2 | c.695G>T p.W232L | Missense Mutation (SNP) | VAF 59/528 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60369301; called by muse, mutect2, varscan2
- KCNU1 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV67758679; called by muse, varscan2
- KIR3DL1 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 81/563 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100428809; called by muse, mutect2, varscan2
- KYNU | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 89/691 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs374687401; called by muse, mutect2, varscan2
- LRRN3 | c.265G>C p.D89H | Missense Mutation (SNP) | VAF 73/465 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100072754; called by muse, mutect2, varscan2
- MAGEA1 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 76/447 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV63118550; called by muse, mutect2, varscan2
- MAGEE2 | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV104428903; called by muse, mutect2
- MCTP1 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 41/308 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759377581; called by muse, mutect2, varscan2
- MGAM2 | c.5563A>G p.T1855A | Missense Mutation (SNP) | VAF 52/322 reads (16%) | SIFT deleterious, low confidence (0.01); catalogued as rs1295044720; called by muse, mutect2, varscan2
- NGEF | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.551); catalogued as COSV50918672; called by muse, mutect2, varscan2
- NIPSNAP2 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 55/412 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.342); catalogued as COSV59052183; called by muse, mutect2, varscan2
- NLGN1 | c.1277C>A p.P426H | Missense Mutation (SNP) | VAF 50/323 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.911); catalogued as COSV64333064; called by muse, mutect2, varscan2
- NRXN1 | c.3262C>A p.Q1088K | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV58478392; called by muse, mutect2, varscan2
- NUF2 | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 34/291 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as rs746568095, COSV54847096; called by muse, mutect2, varscan2
- OR51L1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs746749251; called by muse, mutect2, varscan2
- OR6P1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58108624; called by muse, mutect2
- PCDHGA5 | c.90G>T p.Q30H | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.208); catalogued as COSV99544908; called by muse, mutect2, varscan2
- PDHA2 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 69/489 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV54780374; called by muse, mutect2, varscan2
- PDZRN3 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 36/415 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374072937; called by muse, mutect2
- PKHD1L1 | c.3184G>C p.D1062H | Missense Mutation (SNP) | VAF 30/258 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV65750230; called by muse, mutect2, varscan2
- POTEG | c.268G>C p.A90P | Missense Mutation (SNP) | VAF 154/2450 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.265); catalogued as COSV73630379; called by muse, mutect2
- PRDM9 | c.2317G>T p.E773* | Nonsense Mutation (SNP) | VAF 123/968 reads (13%) | catalogued as rs550917615, COSV57005467, COSV57011238; called by muse, varscan2
- PRSS1 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 61/491 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757218067, COSV61193118; called by muse, varscan2
- RAF1 | c.308A>G p.H103R | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52584692; called by muse, mutect2
- RP1L1 | c.3571G>T p.E1191* | Nonsense Mutation (SNP) | VAF 90/582 reads (15%) | catalogued as COSV66753217; called by mutect2, varscan2
- RPL10L | c.574C>A p.P192T | Missense Mutation (SNP) | VAF 76/502 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV53559693; called by muse, mutect2, varscan2
- SCN11A | c.4402G>T p.A1468S | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV56570182; called by muse, mutect2, varscan2
- SETBP1 | c.3718C>T p.Q1240* | Nonsense Mutation (SNP) | VAF 52/586 reads (9%) | catalogued as COSV56315910; called by muse, mutect2
- SIRPG | c.658G>T p.V220F | Missense Mutation (SNP) | VAF 53/507 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.794); catalogued as COSV99403594; called by muse, mutect2, varscan2
- SKOR1 | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV58244651; called by muse, mutect2, varscan2
- SMC2 | c.233C>A p.S78Y | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs745778970; called by muse, mutect2
- SMCHD1 | c.1121T>C p.I374T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs1456347365; called by muse, mutect2, varscan2
- SMIM6 | c.173C>A p.A58E | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781397437; called by muse, mutect2, varscan2
- SPATA22 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 60/527 reads (11%) | catalogued as rs1049233884; called by muse, mutect2, varscan2
- SRD5A2 | c.691C>G p.H231D | Missense Mutation (SNP) | VAF 42/266 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1241588085; called by muse, mutect2, varscan2
- STRN4 | c.1755del p.T586Qfs*59 | Frame Shift Del (DEL) | VAF 14/90 reads (16%) | catalogued as rs1473889792; called by mutect2, pindel, varscan2
- TAS2R1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66779221; called by muse, mutect2, varscan2
- TCEAL2 | c.152del p.G51Afs*8 | Frame Shift Del (DEL) | VAF 102/881 reads (12%) | catalogued as COSV61197310; called by mutect2, pindel, varscan2
- TECRL | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 71/544 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV67090011; called by muse, mutect2, varscan2
- TFAP2B | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 75/491 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV53827820; called by muse, mutect2, varscan2
- TNR | c.917A>T p.Q306L | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs777624185; called by muse, mutect2, varscan2
- UNC45B | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 33/196 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as COSV52101694; called by muse, mutect2, varscan2
- UNC79 | c.6179C>A p.T2060N (on ENST00000393151 / NM_001346218.2; = p.T1883N on NM_020818.5) | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs77267660; called by muse, mutect2
- VPS26A | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 37/287 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as COSV99697507; called by muse, mutect2, varscan2
- ZNF804B | c.3885G>T p.L1295F | Missense Mutation (SNP) | VAF 82/432 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.24); catalogued as COSV60836544; called by muse, mutect2, varscan2
- ZNF862 | c.1630G>T p.V544F | Missense Mutation (SNP) | VAF 98/638 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.088); catalogued as rs894976352; called by muse, mutect2, varscan2
- ABCA7 | c.3014G>T p.G1005V | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AC100868.1 | c.1378G>T p.E460* | Nonsense Mutation (SNP) | VAF 32/376 reads (9%) | called by muse, mutect2
- ACTN1 | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- ADCY1 | c.2328G>T p.G776= | Splice Region (SNP) | VAF 20/91 reads (22%) | called by muse, mutect2, varscan2
- ADCY2 | c.3242C>A p.S1081* | Nonsense Mutation (SNP) | VAF 39/219 reads (18%) | called by muse, mutect2, varscan2
- ADGRB1 | c.4102C>A p.H1368N | Missense Mutation (SNP) | VAF 56/356 reads (16%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL1 | c.1955A>T p.N652I | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK2 | c.6205del p.Y2069Tfs*10 | Frame Shift Del (DEL) | VAF 21/179 reads (12%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF19 | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 73/497 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARL13A | c.614dup p.N206Efs*2 | Frame Shift Ins (INS) | VAF 53/350 reads (15%) | called by mutect2, pindel, varscan2
- ARMCX5 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- ATXN1L | c.1381A>T p.T461S | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BPIFB4 | c.1824C>G p.D608E | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- C17orf99 | c.157del p.Q53Sfs*23 | Frame Shift Del (DEL) | VAF 57/467 reads (12%) | called by mutect2, pindel, varscan2
- CACNA1G | c.4051G>T p.G1351W | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAMK2B | c.1673+7C>A | Splice Region (SNP) | VAF 29/212 reads (14%) | called by muse, mutect2, varscan2
- CDC42BPA | c.3844G>T p.V1282L (on ENST00000334218 / NM_001366019.2; = p.V1269L on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CLCN1 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 78/531 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNKSR1 | c.1243G>T p.A415S (on ENST00000374253 / NM_001297647.2; = p.A408S on NM_006314.3) | Missense Mutation (SNP) | VAF 54/336 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COL21A1 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A5 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 86/617 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- COL5A1 | c.3889G>T p.G1297* | Nonsense Mutation (SNP) | VAF 25/234 reads (11%) | called by muse, mutect2, varscan2
- CRY2 | c.166C>A p.L56I | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.172); called by muse, mutect2
- CTAGE1 | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 76/684 reads (11%) | called by muse, mutect2, varscan2
- DAXX | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2
- DMD | c.9140C>G p.P3047R | Missense Mutation (SNP) | VAF 97/694 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYTN | c.1389del p.R464Gfs*24 | Frame Shift Del (DEL) | VAF 71/438 reads (16%) | called by mutect2, pindel, varscan2
- EEA1 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EGFL6 | c.74G>C p.S25T | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- EPHA6 | c.555G>T p.W185C | Missense Mutation (SNP) | VAF 55/328 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- FADS1 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 72/507 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FAM83B | c.2534G>C p.S845T | Missense Mutation (SNP) | VAF 62/412 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FAT4 | c.2621C>T p.T874I | Missense Mutation (SNP) | VAF 38/250 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- FGF13 | c.208G>T p.V70F | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FMNL1 | c.3109del p.R1037Gfs*10 | Frame Shift Del (DEL) | VAF 31/127 reads (24%) | called by mutect2, pindel*, varscan2*
- FOLH1 | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 68/363 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- FOXL1 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 85/526 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- GABRB2 | c.1138G>T p.G380* | Nonsense Mutation (SNP) | VAF 51/352 reads (14%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 59/480 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GP6 | c.763G>T p.D255Y | Missense Mutation (SNP) | VAF 69/521 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPATCH1 | c.1678T>A p.S560T | Missense Mutation (SNP) | VAF 81/542 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GPR33 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 46/301 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- HAUS6 | c.1895G>C p.R632T | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- HERC1 | c.384G>T p.K128N | Missense Mutation (SNP) | VAF 32/298 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.107); called by muse, mutect2
- HEYL | c.147+1G>T p.X49_splice | Splice Site (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- HHIPL2 | c.1042G>A p.G348S | Missense Mutation (SNP) | VAF 58/526 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IAPP | c.222T>A p.N74K | Missense Mutation (SNP) | VAF 57/344 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- IGFN1 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- IGSF1 | c.3923G>T p.C1308F | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.168); called by muse, mutect2
- IL1RAPL1 | c.578G>T p.S193I | Missense Mutation (SNP) | VAF 49/467 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- INPP4B | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- JPH3 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1217 | c.358A>T p.R120W | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- KLHL35 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- KREMEN2 | c.1229G>A p.R410K (on ENST00000303746 / NM_172229.3; = p.G384R on NM_024507.4) | Missense Mutation (SNP) | VAF 20/169 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- KRT18 | c.899G>T p.R300I | Missense Mutation (SNP) | VAF 145/926 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LAMA4 | c.4259C>T p.S1420F (on ENST00000230538 / NM_001105206.3; = p.S1413F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/350 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LAMC1 | c.2849G>C p.R950P | Missense Mutation (SNP) | VAF 47/390 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LGR5 | c.2363C>A p.S788Y | Missense Mutation (SNP) | VAF 64/416 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, varscan2
- LONRF3 | c.1697C>A p.P566H (on ENST00000371628 / NM_001031855.3; = p.P525H on NM_024778.5) | Missense Mutation (SNP) | VAF 57/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LPAR3 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 98/644 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP5 | c.3713G>T p.C1238F | Missense Mutation (SNP) | VAF 80/545 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEA12 | c.596C>G p.T199R | Missense Mutation (SNP) | VAF 102/808 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MAGEB6B | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 59/543 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- MAP3K6 | c.3714G>T p.L1238= | Splice Region (SNP) | VAF 51/367 reads (14%) | called by muse, mutect2, varscan2
- MGA | c.569G>T p.G190V | Missense Mutation (SNP) | VAF 59/467 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MID2 | c.490del p.R164Vfs*40 | Frame Shift Del (DEL) | VAF 22/225 reads (10%) | called by mutect2, pindel, varscan2
- MLYCD | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- MMGT1 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 65/534 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MRPL48 | c.355A>G p.I119V | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MTA1 | c.1229del p.P410Lfs*21 | Frame Shift Del (DEL) | VAF 59/351 reads (17%) | called by mutect2, pindel, varscan2
- MUC5B | c.10047del p.S3350Pfs*13 | Frame Shift Del (DEL) | VAF 78/605 reads (13%) | called by mutect2, pindel, varscan2
- MYH1 | c.5480A>T p.E1827V | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NALCN | c.2549G>A p.C850Y | Missense Mutation (SNP) | VAF 31/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NEU2 | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKG7 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by mutect2, varscan2
- OPN5 | c.1059G>T p.W353C | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2T1 | c.889A>T p.T297S | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR5L2 | c.604G>C p.V202L | Missense Mutation (SNP) | VAF 53/364 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- OR6P1 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 101/726 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR6P1 | c.548C>A p.P183Q | Missense Mutation (SNP) | VAF 44/454 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OTUD5 | c.1003T>G p.Y335D | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PASD1 | c.1949T>G p.V650G | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- PCCB | c.1405G>C p.V469L | Missense Mutation (SNP) | VAF 50/642 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); called by muse, mutect2
- PCDHB6 | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 147/1262 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCSK7 | c.1063G>T p.D355Y | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDX1 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNB3 | c.3029G>T p.R1010L | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- POTEE | c.635A>T p.K212M | Missense Mutation (SNP) | VAF 78/668 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); called by muse, varscan2
- PPM1E | c.1344A>C p.K448N | Missense Mutation (SNP) | VAF 42/330 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.07); called by mutect2, varscan2
- PPP1R26 | c.1412C>G p.S471C | Missense Mutation (SNP) | VAF 26/407 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.719); called by muse, mutect2
- PRR5L | c.581T>C p.L194P | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PSTPIP1 | c.151del p.E51Sfs*23 | Frame Shift Del (DEL) | VAF 25/205 reads (12%) | called by mutect2, pindel, varscan2
- RIMS2 | c.3709A>T p.S1237C | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RND3 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 50/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RPL5 | c.637G>T p.E213* | Nonsense Mutation (SNP) | VAF 76/546 reads (14%) | called by muse, mutect2, varscan2
- RPS6KA3 | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 53/370 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.7147C>A p.H2383N | Missense Mutation (SNP) | VAF 29/288 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SCGB2A1 | c.56-2A>T p.X19_splice | Splice Site (SNP) | VAF 16/111 reads (14%) | called by mutect2, varscan2
- SHROOM2 | c.3704C>A p.P1235Q | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- SMG6 | c.3050C>G p.P1017R | Missense Mutation (SNP) | VAF 53/419 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- SMNDC1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- SPANXN1 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 35/450 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2
- SPATA31A1 | c.3828G>C p.Q1276H | Missense Mutation (SNP) | VAF 57/1002 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2
- SPRYD3 | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 50/421 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- SUGP1 | c.1271del p.E424Gfs*8 | Frame Shift Del (DEL) | VAF 30/257 reads (12%) | called by mutect2, pindel, varscan2
- SVEP1 | c.3527C>A p.P1176H | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.436); called by muse, mutect2
- TJP2 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 69/446 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- TMEM235 | c.139G>C p.G47R | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- TRAJ57 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 33/223 reads (15%) | called by muse, mutect2, varscan2
- TRPC4 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 42/390 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TTC8 | c.353A>G p.Q118R (on ENST00000338104 / NM_001288781.1; = p.Q128R on NM_144596.4) | Missense Mutation (SNP) | VAF 113/666 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TTLL7 | c.1073C>A p.T358N | Missense Mutation (SNP) | VAF 52/383 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- UGT1A5 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 92/649 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- USP28 | c.1793C>T p.A598V | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UTP25 | c.1387G>C p.G463R | Missense Mutation (SNP) | VAF 83/719 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP25 | c.1388G>T p.G463V | Missense Mutation (SNP) | VAF 86/712 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASH6P | c.547G>C p.V183L | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); called by mutect2, varscan2
- WDR27 | c.2408G>T p.G803V | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- WNT2B | c.382T>C p.F128L (on ENST00000369684 / NM_024494.3; = p.F109L on NM_004185.4) | Missense Mutation (SNP) | VAF 80/472 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- WNT9A | c.863A>G p.E288G | Missense Mutation (SNP) | VAF 47/336 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- WWC1 | c.942-1G>T p.X314_splice | Splice Site (SNP) | VAF 37/217 reads (17%) | called by muse, varscan2
- YY2 | c.176T>A p.L59* | Nonsense Mutation (SNP) | VAF 72/436 reads (17%) | called by muse, mutect2, varscan2
- ZFHX4 | c.10558dup p.C3520Lfs*9 | Frame Shift Ins (INS) | VAF 64/491 reads (13%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.162+1G>A p.X54_splice | Splice Site (SNP) | VAF 33/234 reads (14%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.1145G>T p.R382L | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF311 | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 73/478 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF492 | c.1186G>C p.E396Q | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF705A | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 46/599 reads (8%) | called by muse, mutect2
- ZNF831 | c.4922C>T p.A1641V | Missense Mutation (SNP) | VAF 38/390 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.294); called by muse, mutect2
- ZNF90 | c.454A>G p.K152E | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- ZP1 | c.1432T>G p.C478G | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZPLD1 | c.829G>A p.E277K (on ENST00000466937 / NM_001329788.1; = p.E293K on NM_175056.2) | Missense Mutation (SNP) | VAF 39/283 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ABCA9 | c.3865C>A p.R1289= | Silent (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
- ADAD2 | c.1338C>T p.C446= (on ENST00000315906 / NM_001145400.2; = p.C528= on NM_139174.4) | Silent (SNP) | VAF 35/243 reads (14%) | called by muse, mutect2, varscan2
- ADCY5 | c.2514G>A p.G838= | Silent (SNP) | VAF 63/419 reads (15%) | called by muse, varscan2
- ADIRF | c.54G>A p.Q18= | Silent (SNP) | VAF 32/212 reads (15%) | catalogued as rs866670301; called by muse, mutect2, varscan2
- AFF2 | c.3708C>A p.P1236= | Silent (SNP) | VAF 31/377 reads (8%) | catalogued as COSV54009878; called by muse, mutect2
- AK5 | c.900C>T p.A300= (on ENST00000354567 / NM_174858.3; = p.A274= on NM_012093.4) | Silent (SNP) | VAF 57/267 reads (21%) | catalogued as rs140334353, COSV100643524; called by muse, mutect2, varscan2
- ANXA8 | c.402G>T p.A134= | Silent (SNP) | VAF 54/990 reads (5%) | called by muse, mutect2
- APOB | c.4482G>A p.S1494= | Silent (SNP) | VAF 36/278 reads (13%) | catalogued as rs769700242, COSV51951658; called by muse, mutect2, varscan2
- ATP11C | c.1179G>A p.L393= | Silent (SNP) | VAF 35/248 reads (14%) | called by muse, varscan2
- ATXN2L | c.1812G>T p.S604= | Silent (SNP) | VAF 93/590 reads (16%) | called by muse, mutect2, varscan2
- CARD11 | c.384G>T p.T128= | Silent (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2
- DCAF4L2 | c.588G>T p.A196= | Silent (SNP) | VAF 121/790 reads (15%) | catalogued as COSV60479866, COSV60482852; called by muse, mutect2, varscan2
- DCX | c.57A>T p.R19= | Silent (SNP) | VAF 48/312 reads (15%) | called by muse, mutect2, varscan2
- DENND5B | c.798C>T p.L266= | Silent (SNP) | VAF 14/78 reads (18%) | called by muse, mutect2
- DKC1 | c.804T>C p.D268= | Silent (SNP) | VAF 62/1022 reads (6%) | called by muse, mutect2
- DNAH17 | c.7704C>A p.A2568= | Silent (SNP) | VAF 59/424 reads (14%) | called by muse, mutect2, varscan2
- DNER | c.1824G>T p.P608= | Silent (SNP) | VAF 33/166 reads (20%) | catalogued as rs202150174, COSV100518393; called by muse, mutect2, varscan2
- FAM47C | c.1176A>G p.P392= | Silent (SNP) | VAF 64/534 reads (12%) | called by muse, mutect2, varscan2
- GABRA3 | c.576C>G p.P192= | Silent (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2, varscan2
- GDF10 | c.564C>A p.R188= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- HMCN1 | c.3354G>A p.Q1118= | Silent (SNP) | VAF 83/676 reads (12%) | called by muse, mutect2, varscan2
- IFI16 | c.1002C>T p.Y334= | Silent (SNP) | VAF 67/517 reads (13%) | catalogued as rs199556510, COSV99858007; called by muse, mutect2, varscan2
- IGSF9B | c.471C>T p.I157= | Silent (SNP) | VAF 57/441 reads (13%) | catalogued as rs761303400; called by muse, mutect2, varscan2
- IMPDH1 | c.753C>T p.T251= (on ENST00000470772 / NM_001142573.2; = p.T337= on NM_000883.4) | Silent (SNP) | VAF 38/227 reads (17%) | catalogued as COSV58317904; called by muse, mutect2, varscan2
- KCNA6 | c.1395C>T p.Y465= | Silent (SNP) | VAF 40/347 reads (12%) | catalogued as COSV54976136; called by muse, mutect2, varscan2
- KCNK10 | c.258C>A p.G86= | Silent (SNP) | VAF 108/641 reads (17%) | catalogued as COSV104394971; called by muse, mutect2, varscan2
- LRRC7 | c.3507C>G p.V1169= (on ENST00000651989 / NM_001370785.2; = p.V1136= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/346 reads (13%) | catalogued as COSV50418135; called by muse, mutect2, varscan2
- MLC1 | c.495G>A p.R165= | Silent (SNP) | VAF 67/470 reads (14%) | called by muse, mutect2, varscan2
- MUC16 | c.30945T>A p.A10315= | Silent (SNP) | VAF 23/143 reads (16%) | called by muse, mutect2, varscan2
- NYNRIN | c.654G>T p.P218= | Silent (SNP) | VAF 79/573 reads (14%) | called by muse, mutect2, varscan2
- OCA2 | c.1170G>T p.L390= | Silent (SNP) | VAF 84/840 reads (10%) | called by muse, mutect2, varscan2
- ODF2L | c.1068A>T p.P356= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs1252015476; called by muse, mutect2, varscan2
- OLIG3 | c.501G>T p.S167= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs571723366, COSV100880198; called by muse, mutect2, varscan2
- OLR1 | c.753T>A p.V251= | Silent (SNP) | VAF 30/185 reads (16%) | called by muse, mutect2, varscan2
- OR5AS1 | c.555G>T p.L185= | Silent (SNP) | VAF 69/446 reads (15%) | called by muse, mutect2, varscan2
- OR9I1 | c.657G>T p.L219= | Silent (SNP) | VAF 74/466 reads (16%) | called by muse, mutect2, varscan2
- PAX4 | c.382C>T p.L128= | Silent (SNP) | VAF 111/814 reads (14%) | catalogued as rs1406069827, COSV58388032; called by muse, mutect2, varscan2
- PEX2 | c.876A>G p.P292= | Silent (SNP) | VAF 77/519 reads (15%) | called by muse, mutect2, varscan2
- PHEX | c.1893C>A p.G631= | Silent (SNP) | VAF 59/560 reads (11%) | called by muse, mutect2, varscan2
- PLEKHN1 | c.1623C>T p.P541= (on ENST00000379409; = p.P489= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/203 reads (16%) | called by muse, mutect2, varscan2
- PPT2 | c.75G>A p.L25= | Silent (SNP) | VAF 39/271 reads (14%) | catalogued as rs759240503; called by muse, mutect2, varscan2
- PTPRR | c.1320C>A p.T440= | Silent (SNP) | VAF 19/228 reads (8%) | catalogued as rs760350679; called by muse, mutect2
- RALYL | c.63C>T p.S21= | Silent (SNP) | VAF 69/514 reads (13%) | catalogued as rs373186367, COSV72820920; called by muse, mutect2, varscan2
- RMND5B | c.720G>C p.L240= | Silent (SNP) | VAF 28/209 reads (13%) | catalogued as rs146514336; called by muse, mutect2, varscan2
- RNF223 | c.345G>A p.L115= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- RNPEPL1 | c.810C>T p.D270= | Silent (SNP) | VAF 15/105 reads (14%) | called by muse, mutect2, varscan2
- ROBO2 | c.2793G>T p.T931= | Silent (SNP) | VAF 77/462 reads (17%) | called by muse, mutect2, varscan2
- SLC18A1 | c.1239C>A p.I413= | Silent (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- SLC30A10 | c.111G>C p.L37= | Silent (SNP) | VAF 46/586 reads (8%) | called by muse, mutect2
- SPATA31D4 | c.2361G>A p.E787= | Silent (SNP) | VAF 80/369 reads (22%) | called by muse, mutect2, varscan2
- TACC1 | c.429T>C p.F143= | Silent (SNP) | VAF 78/605 reads (13%) | catalogued as rs868400944; called by muse, mutect2, varscan2
- TARBP1 | c.1173G>T p.L391= | Silent (SNP) | VAF 12/190 reads (6%) | called by muse, mutect2
- TMSB4X | c.69G>T p.T23= | Silent (SNP) | VAF 90/764 reads (12%) | catalogued as rs1468143765, COSV66081143; called by muse, mutect2, varscan2
- TNIP3 | c.267G>C p.R89= | Silent (SNP) | VAF 102/749 reads (14%) | called by muse, mutect2, varscan2
- TRPS1 | c.1104C>T p.S368= (on ENST00000220888 / NM_001330599.2; = p.S381= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 70/483 reads (14%) | catalogued as rs768826101; called by muse, mutect2, varscan2
- TSEN54 | c.61C>A p.R21= | Silent (SNP) | VAF 16/87 reads (18%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1383G>T p.V461= (on ENST00000580243 / NM_001308210.2; = p.V416= on NM_005786.6) | Silent (SNP) | VAF 39/266 reads (15%) | called by muse, mutect2, varscan2
- UBR4 | c.11385C>T p.Y3795= | Silent (SNP) | VAF 42/288 reads (15%) | catalogued as rs749762161, COSV64399650; called by muse, mutect2, varscan2
- UMODL1 | c.453G>T p.G151= | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as COSV68555267; called by muse, mutect2, varscan2
- UNC79 | c.6180C>A p.T2060= (on ENST00000393151 / NM_001346218.2; = p.T1883= on NM_020818.5) | Silent (SNP) | VAF 26/284 reads (9%) | catalogued as COSV99827183; called by muse, mutect2
- VGLL1 | c.144T>A p.A48= | Silent (SNP) | VAF 38/380 reads (10%) | called by muse, mutect2
- ZNF536 | c.1626T>C p.H542= | Silent (SNP) | VAF 50/366 reads (14%) | called by muse, mutect2, varscan2
- ZYX | c.1564C>A p.R522= | Silent (SNP) | VAF 49/369 reads (13%) | catalogued as COSV99313526; called by muse, mutect2, varscan2
- AC009139.2 | n.64+1879G>A | Intron (SNP) | VAF 16/157 reads (10%) | called by muse, mutect2
- AC018563.1 | chr15:36880126 T>C | 3'Flank (SNP) | VAF 66/708 reads (9%) | called by muse, mutect2
- AC073648.1 | n.560G>T | RNA (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- AGAP12P | n.686C>A | RNA (SNP) | VAF 106/1384 reads (8%) | called by muse, mutect2
- ALPI | c.68-9C>A | Intron (SNP) | VAF 116/623 reads (19%) | catalogued as rs748867233; called by muse, mutect2, varscan2
- CLCN2 | c.1327-45G>T | Intron (SNP) | VAF 12/164 reads (7%) | catalogued as rs1173175878; called by muse, mutect2
- CLK2P1 | n.637C>T | RNA (SNP) | VAF 124/901 reads (14%) | called by muse, mutect2, varscan2
- DCTN5 | c.118-1010A>G | Intron (SNP) | VAF 12/141 reads (9%) | catalogued as rs991767087; called by muse, mutect2
- EPHX1 | c.364+49G>T | Intron (SNP) | VAF 39/307 reads (13%) | called by muse, mutect2, varscan2
- FOXP2 | c.*1117T>C | 3'UTR (SNP) | VAF 100/692 reads (14%) | called by muse, mutect2, varscan2
- GALNT9 | c.1077+7339G>T | Intron (SNP) | VAF 40/232 reads (17%) | catalogued as rs879999740, COSV61097553; called by muse, mutect2
- GRM1 | c.2661-7293C>A | Intron (SNP) | VAF 60/338 reads (18%) | catalogued as COSV99264108; called by muse, mutect2, varscan2
- IFIT5 | chr10:89412807 C>G | 5'Flank (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2
- KNSTRN | c.486-296G>T | Intron (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- MTM1 | c.-3A>T | 5'UTR (SNP) | VAF 26/406 reads (6%) | called by muse, mutect2
- PDPR | c.1963-840G>A | Intron (SNP) | VAF 22/302 reads (7%) | called by muse, mutect2
- PEX5L | c.94-2430G>A | Intron (SNP) | VAF 44/337 reads (13%) | catalogued as COSV55850603; called by muse, mutect2, varscan2
- PGAP2 | c.166-919G>A | Intron (SNP) | VAF 54/407 reads (13%) | called by muse, mutect2, varscan2
- PIEZO1 | c.161-603G>T | Intron (SNP) | VAF 8/72 reads (11%) | called by mutect2, varscan2
- RBM7 | chr11:114413979 T>C | 3'Flank (SNP) | VAF 31/210 reads (15%) | catalogued as rs1446135767; called by muse, mutect2, varscan2
- RBM7 | chr11:114413980 G>T | 3'Flank (SNP) | VAF 32/218 reads (15%) | catalogued as rs1286130170; called by muse, varscan2
- RTN1 | c.1766-2635T>A | Intron (SNP) | VAF 35/308 reads (11%) | called by muse, mutect2, varscan2
- SIRPB2 | c.*21G>A | 3'UTR (SNP) | VAF 38/284 reads (13%) | catalogued as rs771462582; called by muse, mutect2, varscan2
- SLC48A1 | chr12:47770920 C>T | 5'Flank (SNP) | VAF 59/397 reads (15%) | called by muse, mutect2, varscan2
- TG | c.7239+17736T>G | Intron (SNP) | VAF 33/279 reads (12%) | called by muse, mutect2
- TLE4 | c.-27C>A | 5'UTR (SNP) | VAF 27/383 reads (7%) | catalogued as rs781403946; called by muse, mutect2
- TMEM161B | chr5:88190113 C>A | 3'Flank (SNP) | VAF 34/422 reads (8%) | called by muse, mutect2
- ZEB1 | c.58+43817G>A | Intron (SNP) | VAF 95/689 reads (14%) | catalogued as rs1314183284; called by muse, mutect2, varscan2
- ZNF185 | c.1209-3468G>T | Intron (SNP) | VAF 38/200 reads (19%) | called by muse, mutect2, varscan2
